MMRF case MMRF_1086 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ea3cf008-6883-41ff-928a-aedb01128468

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 67.0 years (24,467 days); ISS stage: I; Days to last known disease status: 1,782 days (4.9 years); Days to last follow up: 1,782 days (4.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 142 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 23 days; Days to treatment end: 114 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 176 days; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 257 days; Days to treatment end: 358 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -9: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 59.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.82 mg/dL; Immunoglobulin G 7.41 g/L; Immunoglobulin A 0.659 g/L; Immunoglobulin M 0.291 g/L; Beta 2 Microglobulin 2 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 4.95 mmol/L.
- Day 107: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 9.15 g/L; Immunoglobulin A 0.894 g/L; Immunoglobulin M 0.579 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.37 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 132 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 5.56 mmol/L.
- Day 174: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.36 mg/dL; Immunoglobulin G 9.72 g/L; Immunoglobulin A 0.951 g/L; Immunoglobulin M 0.676 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.7 ×10⁹/L; Platelets 326 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 7.59 mmol/L.
- Day 257 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.216 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.4 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 4.13 mmol/L.
- Day 361: Serum Free Immunoglobulin Light Chain, Kappa 15.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.2 mg/dL; Immunoglobulin G 9.95 g/L; Beta 2 Microglobulin 1.9 µg/mL; Hemoglobin 5.15 mmol/L; Leukocytes 2.06 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 35.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 33 g/L; Total Protein 6.2 g/dL; Glucose 5.5 mmol/L.
- Day 435: Hemoglobin 7.38 mmol/L; Leukocytes 2.5 ×10⁹/L; Platelets 174 ×10⁹/L.
- Day 550 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 8.78 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 10.4 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 218 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 5.67 mmol/L.
- Day 624 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.22 mg/dL; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.38 mmol/L; Leukocytes 3.1 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.35 mmol/L; Albumin 44 g/L; Total Protein 7.1 g/dL; Glucose 4.51 mmol/L.
- Day 717: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.815 mg/dL; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.6 g/dL; Glucose 4.57 mmol/L.
- Day 827 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.777 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.622 mg/dL; Beta 2 Microglobulin 1.8 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 204 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 4.46 mmol/L.
- Day 904 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.77 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.7 mg/dL; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.45 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 4.29 mmol/L.
- Day 995 (ECOG 0): Immunoglobulin G 11.5 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 2.33 µkat/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 4.9 mmol/L.
- Day 1,081 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.59 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.34 g/L; Lactate Dehydrogenase 2.22 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.8 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 53 µmol/L; Glucose 6.11 mmol/L.
- Day 1,145 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 1.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.696 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.47 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 1.8 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 6.33 mmol/L.
- Day 1,262 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.8 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Beta 2 Microglobulin 1.5 µg/mL; Hemoglobin 7.5 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 192 ×10⁹/L.
- Day 1,332: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.966 mg/dL; Beta 2 Microglobulin 1.3 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 3.8 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.
- Day 1,453: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.61 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.5 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.72 mmol/L.
- Day 1,559 (ECOG 0): Immunoglobulin G 10.5 g/L; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 1.4 µg/mL; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 4.51 mmol/L.
- Day 1,690 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 9.58 g/L; Immunoglobulin A 1.52 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 5.12 mmol/L.
- Day 1,782 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.86 mg/dL; Immunoglobulin G 9.98 g/L; Immunoglobulin A 1.58 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 7.87 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 43 g/L; Total Protein 6.6 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day -9: Weight: 59 kg; Height: 157 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1086_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -9 days.
- Sample MMRF_1086_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -9 days.
